Gene-level copy-number profile of tumor specimen TCGA-FS-A1ZP-06A from TCGA case TCGA-FS-A1ZP, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.4 years (19,864 days).
Specimen TCGA-FS-A1ZP-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.48c9bdb7-111a-48da-8b2f-330bff1297a5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FS-A1ZP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/57e7bad1-1a1e-47fd-b58c-434d0148ceb2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,651; copy number 2: 46,928; copy number 3: 3,817; copy number 4: 4,200; copy number 5: 192; copy number 6: 632; copy number 8: 133; copy number 9: 12; copy number 10: 153; copy number 11: 97.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FS-A1ZP-06A-11D-A191-01): tumor purity 0.81, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,219 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:247,034,637–248,919,946, 108 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:57,240,057–59,137,502, 31 genes, copy number 8: AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1, RPL30P10, AC068075.2, AC090796.1, AC104051.1, AC104051.2, LINC01602, AC012103.1, FAM110B, AC104350.1, AC027698.1, RPL26P26, AC092819.3, AC092819.1, AC092819.2, UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1.
- chr8:59,760,047–84,921,844, 364 genes, copy number 8–11 (within-gene range 3–11) (broad region; genes not listed).
- chr14:21,868,839–22,507,723, 84 genes, copy number 5 (broad region; genes not listed).
- chr15:77,041,404–101,933,350, 632 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,264. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
